Somatic mutation profile of tumor specimen BA2248D (aliquot aq-BA2248D) from BEATAML1.0 case 2105, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.5 years (7,836 days).
Specimen BA2248D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2711d7bf-b1a0-49ca-9a90-6d8bc3700ca9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2444D (Solid Tissue Normal), aliquot aq-BA2444D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a26c2d1-b62f-41d0-9f71-def310bf5cb4

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 4, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 60/138 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, varscan2
- DOCK6 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs372044294, COSV52949032; called by muse, mutect2, varscan2
- EGR2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs794727248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.6838C>A p.L2280I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.992); catalogued as COSV58671651; called by muse, mutect2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 48/129 reads (37%) | catalogued as rs780417788; called by mutect2, varscan2
- RAB11B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60085545; called by muse, mutect2
- ROBO4 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs200599294, COSV60623372; called by muse, mutect2, varscan2
- TTN | c.44134G>A p.G14712R (on ENST00000591111; = p.G7288R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | PolyPhen probably damaging (1); catalogued as rs374866935; called by muse, mutect2, varscan2
- WT1 | c.1104dup p.S369Vfs*4 | Frame Shift Ins (INS) | VAF 168/240 reads (70%) | catalogued as COSV60065450, COSV60070013, COSV60076917, COSV99070067; called by mutect2, pindel, varscan2
- CMTM3 | c.182_183insCC p.S62Rfs*29 | Frame Shift Ins (INS) | VAF 33/86 reads (38%) | called by mutect2, pindel, varscan2
- EPB41L4A | c.1726T>C p.Y576H | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- KMT2E | c.5572C>A p.H1858N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- RLIM | c.1763G>A p.C588Y | Missense Mutation (SNP) | VAF 101/125 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SAFB | c.1497dup p.K500Efs*9 | Frame Shift Ins (INS) | VAF 49/125 reads (39%) | called by mutect2, pindel, varscan2
- CT47B1 | c.108C>T p.G36= | Silent (SNP) | VAF 70/76 reads (92%) | catalogued as rs751014560, COSV64891512; called by muse, mutect2, varscan2
- GRIN2B | c.3774C>T p.N1258= | Silent (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- PIEZO1 | c.2349G>T p.L783= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- RBPMS | c.387C>T p.A129= | Silent (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- UBTF | c.462G>A p.P154= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs375532870; called by muse, mutect2, varscan2
- FEZ1 | c.-282C>T | 5'UTR (SNP) | VAF 60/112 reads (54%) | catalogued as rs775141235; called by muse, mutect2, varscan2
- KLF6 | c.*2410dup | 3'UTR (INS) | VAF 76/241 reads (32%) | catalogued as rs768488009; called by mutect2, pindel, varscan2
